Somatic mutation profile of tumor specimen 0DWM1D from CCDI case PBCNYY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.9 years (3,256 days).
Specimen 0DWM1D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02ccdd01-b184-4005-9d21-8e1208e48ec1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWLYQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ee8b490-edae-4cf5-bc25-60877479a17d

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Nonsense Mutation 1, 5'UTR 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 172/606 reads (28%) | catalogued as rs755455944, COSV52808060; called by muse, varscan2
- KRT7 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 86/287 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); catalogued as rs763632449, COSV100081753; called by muse, varscan2
- ENDOD1 | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 102/482 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- RNF213 | c.1335T>G p.D445E | Missense Mutation (SNP) | VAF 140/710 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, varscan2
- WDR19 | c.1965G>T p.Q655H | Missense Mutation (SNP) | VAF 268/897 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); called by muse, varscan2
- ZBTB5 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 285/740 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, varscan2
- ABCG4 | c.*32C>T | 3'UTR (SNP) | VAF 16/141 reads (11%) | called by muse, varscan2
- CDK5 | c.-2C>A | 5'UTR (SNP) | VAF 96/514 reads (19%) | called by muse, varscan2
- PKD1L2 | n.279G>A | RNA (SNP) | VAF 161/268 reads (60%) | catalogued as rs760002031; called by muse, varscan2
